Surgical pathology report (de-identified scan), TCGA case TCGA-XE-A8H4, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Southern California, specimen TCGA-XE-A8H4-01A (Primary Tumor).

[page 1 of 2]
Ord #=
SURGICAL PATHOL
Modifiers:

RESULTED

Collect ..

(1 of 1)

Surgical Pathology Report

Specimen(s) Received
Left orchiectomy, radical

Clinical History
Left testis mass

ICD-O-3
Seminoma NOS 9061/3
Site of Testis NOS C62.9
JW 11/24/13

Gross Description

Received fresh from the operating room with the patient's name, medical record number and consists of a testis and spermatic cord which weighs 100 grams. The testis measures 7.3 x 5.1 x 4 cm. The spermatic cord measures 6.2 x 1.5 cm. in diameter. The external surface of the specimen is inked black. Serial sectioning reveals a firm, tan mass in the testis measuring 4.5 x 3.5 x 3 cm. There are no necrotic areas or hemorrhagic areas. The remaining testicular parenchyma is the usual pink-tan, soft texture. 1-8

Date of dictation:

Gross Description By:

Microscopic Description
Performed.

Final Pathologic Diagnosis

Speciment Type: Left orchiectomy, radical

-Laterality: Left

-Focality: Unifocal

-Tumor Size: 4.5 x 3.5 x 3 cm

-Histologic Type: Seminoma, classic type.

-Intratubular germ cell neoplasia is not identified.

-Tumor is limited to the testis. Tumor does not involve rete testis, epididymis, perihilar fat, spermatic cord, tunica vaginalis or scrotal wall.

[page 2 of 2]
- Margin: Spermatic cord margin is negative.
- Remaining testicular tissue shows unremarkable.

Pathologic Tumor Stage: pT1NXMXS2 (Stage IA)

Attending Pathologist:

***Electronically Signed Out By

II/III/IV Discrepancy		✓

Source: NCI Genomic Data Commons file f132c147-ffc1-43a6-862a-1f9c9a9c8259 (TCGA-XE-A8H4.63A1426D-9B6D-400C-9754-14F1F5EBE63B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).